Somatic mutation profile of tumor specimen 0DV15A from CCDI case PBCLZT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,861 days).
Specimen 0DV15A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 406b38ad-0f36-4cff-920b-e2f813c991fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc328cfc-aa08-4652-9aab-00bc343cbd20

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDK2 | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 61/1146 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs374738523, COSV101168175; called by muse, mutect2
- ATP6V0C | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 12/377 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- PRPF40A | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 36/566 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- ABCF1 | c.1926G>A p.K642= (on ENST00000326195 / NM_001025091.2; = p.K604= on NM_001090.3) | Silent (SNP) | VAF 43/772 reads (6%) | called by muse, mutect2
- PLXNA3 | c.2475C>A p.T825= | Silent (SNP) | VAF 40/1004 reads (4%) | called by muse, mutect2
- SIGLEC11 | c.135G>A p.P45= | Silent (SNP) | VAF 28/758 reads (4%) | catalogued as rs572754129; called by muse, mutect2
- SHLD2 | c.1964-4156T>C | Intron (SNP) | VAF 26/598 reads (4%) | called by muse, mutect2
